Somatic mutation profile of tumor specimen C3N-02683-02 (aliquot CPT0224930006) from CPTAC case C3N-02683, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 73.2 years (26,747 days).
Specimen C3N-02683-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 214a4e16-6981-407f-9510-a273cade3f1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02683-31 (Blood Derived Normal), aliquot CPT0224950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0625fd02-4514-4615-920e-970c511543b5

The open-access MAF lists 116 somatic variants for this specimen: 72 protein-altering or splice-affecting, 31 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 31, Intron 10, Frame Shift Del 3, Splice Site 2, RNA 1, Frame Shift Ins 1, 3'UTR 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.51); PolyPhen benign (0.366); catalogued as COSV55875690, COSV55899999; called by muse, mutect2, varscan2
- PTPN11 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs397507501, CM021125, COSV61008667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 46/225 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAP1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.7); catalogued as rs765783272, COSV50134614; called by muse, mutect2, varscan2
- CACNA2D1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62377292; called by muse, mutect2, varscan2
- CCDC105 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 63/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1235926446; called by muse, mutect2, varscan2
- CLEC1A | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 174/401 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as rs747354386; called by muse, mutect2, varscan2
- CNTNAP2 | c.1150C>G p.L384V | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV100667600, COSV62157168; called by muse, mutect2, varscan2
- CTAGE1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 75/337 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs576826595; called by muse, mutect2, varscan2
- DDX54 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 64/252 reads (25%) | catalogued as rs746688474; called by muse, mutect2, varscan2
- FRAS1 | c.7054G>A p.V2352M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs767039713; called by muse, mutect2, varscan2
- FZD10 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs770701893, COSV57472020; called by muse, mutect2, varscan2
- GKN1 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs200701146, COSV65006798; called by muse, mutect2, varscan2
- HAVCR1 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 95/420 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs201598799, COSV100208124; called by muse, mutect2, varscan2
- JPH1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs748452859, COSV60608792; called by muse, mutect2, varscan2
- KBTBD13 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1290189270; called by muse, mutect2, varscan2
- KIF3C | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs771331310; called by muse, mutect2, varscan2
- KRT36 | c.1385T>A p.V462E | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100057560; called by muse, mutect2, varscan2
- MPEG1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs200732824; called by muse, mutect2, varscan2
- NF1 | c.499_502del p.C167Qfs*10 | Frame Shift Del (DEL) | VAF 48/96 reads (50%) | catalogued as rs786201874; called by pindel, varscan2
- NLRP7 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 121/496 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759837769, COSV60173232; called by muse, mutect2, varscan2
- NPAP1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.072); catalogued as rs1170974294, COSV61505991; called by muse, mutect2, varscan2
- OR5M11 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs773722172, COSV73141636; called by muse, mutect2, varscan2
- OR5W2 | c.780C>A p.F260L | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.173); catalogued as COSV60615604; called by muse, mutect2, varscan2
- PARP2 | c.1335del p.I445Mfs*35 | Frame Shift Del (DEL) | VAF 51/229 reads (22%) | catalogued as COSV51642050; called by mutect2, pindel, varscan2
- POM121L2 | c.265dup p.L89Pfs*38 | Frame Shift Ins (INS) | VAF 28/141 reads (20%) | catalogued as rs1561791064; called by mutect2, pindel, varscan2
- PRICKLE1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs375459191, COSV61543542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTOV1 | c.1082T>G p.I361S | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs1483681971; called by muse, mutect2, varscan2
- RYR2 | c.9370G>A p.E3124K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs1234350873; called by muse, mutect2, varscan2
- SALL3 | c.2179G>A p.G727S | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as rs762027925, COSV73305838; called by muse, mutect2
- SIRPD | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1482288640; called by muse, mutect2, varscan2
- SLC2A9 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 89/385 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs549642411, COSV53321131; called by muse, mutect2, varscan2
- SLC6A19 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 90/424 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs552867213, COSV100443876; called by muse, mutect2, varscan2
- SLITRK6 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs760544116, COSV68390077; called by muse, mutect2, varscan2
- TBXAS1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 138/735 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs150139510, COSV54950712; called by muse, mutect2, varscan2
- TENM3 | c.8005G>A p.G2669R | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV69308012; called by muse, mutect2, varscan2
- TMEM63B | c.2182G>A p.V728I | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs778979991; called by muse, mutect2, varscan2
- UBA2 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.07); catalogued as rs369462476; called by muse, mutect2, varscan2
- VPS13D | c.12500C>T p.S4167L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV50642699; called by muse, mutect2, varscan2
- WDR97 | c.4121G>A p.R1374H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV60341774; called by muse, mutect2
- XDH | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 103/338 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs150262349; called by muse, mutect2, varscan2
- ZNF208 | c.3334C>A p.P1112T | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769480170; called by muse, mutect2
- ZNF274 | c.937C>T p.R313C (on ENST00000610905; = p.R208C on NM_016324.3) | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs374045776; called by muse, mutect2, varscan2
- ZSCAN1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 50/346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56604954; called by muse, mutect2, varscan2
- ADAMTS12 | c.3014C>A p.P1005Q | Missense Mutation (SNP) | VAF 69/377 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ANKRD63 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 145/411 reads (35%) | SIFT tolerated (0.23); called by muse, mutect2, varscan2
- ASAH2 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 105/243 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CCDC151 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- CCDC38 | c.1394G>T p.R465L | Missense Mutation (SNP) | VAF 142/345 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP131 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CLDN8 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CNTN6 | c.2705-1del p.X902_splice | Splice Site (DEL) | VAF 56/252 reads (22%) | called by mutect2, pindel, varscan2
- CPN1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.094); called by muse, mutect2
- DMTF1 | c.2181A>G p.I727M | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- GPX6 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS2 | c.2696C>T p.T899I | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LAMA3 | c.8855_8856del p.I2952Kfs*79 (on ENST00000313654 / NM_198129.4; = p.I1343Kfs*79 on NM_000227.6) | Frame Shift Del (DEL) | VAF 72/421 reads (17%) | called by mutect2, pindel, varscan2
- MTARC2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MYH11 | c.1570C>T p.R524* | Nonsense Mutation (SNP) | VAF 120/442 reads (27%) | called by muse, mutect2, varscan2
- NBEA | c.348G>C p.E116D | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2A14 | c.812A>G p.K271R | Missense Mutation (SNP) | VAF 42/508 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- OR5W2 | c.779T>G p.F260C | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR7C2 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTOGL | c.3022G>A p.G1008R (on ENST00000547103; = p.G999R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RNF40 | c.1463G>A p.S488N | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); called by muse, mutect2
- SH3TC2 | c.2187G>C p.W729C | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- SLC6A16 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- SNRNP200 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- SPTA1 | c.3727G>T p.G1243W | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TDRD5 | c.2447G>C p.G816A | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- UNC45B | c.1217T>C p.L406P | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XAGE2 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ACY3 | c.192C>T p.Y64= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as rs778074437, COSV99067190; called by muse, mutect2, varscan2
- BRCA2 | c.1167G>A p.P389= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs148607710; ClinVar: conflicting interpretations of pathogenicity / benign / likely benign; called by muse, mutect2, varscan2
- CACNA1D | c.5784G>T p.L1928= (on ENST00000350061 / NM_001128840.3; = p.L1948= on NM_000720.4) | Silent (SNP) | VAF 42/437 reads (10%) | called by muse, mutect2
- CMYA5 | c.10872G>A p.Q3624= | Silent (SNP) | VAF 77/375 reads (21%) | called by muse, mutect2, varscan2
- CNTN4 | c.2223C>G p.P741= | Silent (SNP) | VAF 72/244 reads (30%) | catalogued as COSV61883144; called by muse, mutect2
- COL6A6 | c.672C>T p.G224= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100650200; called by muse, mutect2, varscan2
- DCST2 | c.1570C>A p.R524= | Silent (SNP) | VAF 61/333 reads (18%) | catalogued as COSV55050396; called by muse, mutect2, varscan2
- ETNPPL | c.579G>T p.V193= | Silent (SNP) | VAF 47/207 reads (23%) | catalogued as rs781118542, COSV56595983, COSV56598168; called by muse, mutect2, varscan2
- FGF14 | c.570C>T p.T190= | Silent (SNP) | VAF 49/183 reads (27%) | catalogued as COSV65957569; called by muse, mutect2, varscan2
- FLG | c.7596G>A p.S2532= | Silent (SNP) | VAF 199/462 reads (43%) | catalogued as rs142026832; called by muse, mutect2, varscan2
- FLNB | c.3360G>C p.G1120= | Silent (SNP) | VAF 45/149 reads (30%) | called by muse, mutect2, varscan2
- GPR182 | c.342G>A p.T114= | Silent (SNP) | VAF 34/194 reads (18%) | catalogued as rs960735731; called by muse, mutect2, varscan2
- HCN2 | c.2469G>A p.S823= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV52117028; called by muse, mutect2
- HMCN2 | c.10758G>A p.R3586= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- INTS1 | c.3573C>T p.D1191= | Silent (SNP) | VAF 58/389 reads (15%) | catalogued as rs777576097; called by muse, mutect2, varscan2
- JRK | c.858A>C p.I286= | Silent (SNP) | VAF 220/597 reads (37%) | called by muse, mutect2, varscan2
- LRP2 | c.10704G>A p.P3568= | Silent (SNP) | VAF 69/239 reads (29%) | catalogued as rs756473581, COSV55565974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MDGA1 | c.1284C>T p.S428= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs199847584; called by muse, mutect2
- MYOM2 | c.3945C>T p.S1315= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- NDST4 | c.2091A>C p.S697= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV52120219; called by muse, mutect2
- NUF2 | c.828T>C p.Y276= | Silent (SNP) | VAF 88/186 reads (47%) | catalogued as rs200015425; called by muse, mutect2, varscan2
- PDZRN4 | c.2601G>A p.Q867= (on ENST00000402685 / NM_001164595.2; = p.Q609= on NM_013377.4) | Silent (SNP) | VAF 95/205 reads (46%) | called by muse, mutect2, varscan2
- RAI1 | c.1182C>T p.P394= | Silent (SNP) | VAF 74/203 reads (36%) | catalogued as rs761942418; called by muse, mutect2, varscan2
- RPL23A | c.183T>A p.P61= | Silent (SNP) | VAF 65/214 reads (30%) | called by muse, mutect2, varscan2
- SLC22A16 | c.726G>A p.A242= | Silent (SNP) | VAF 24/141 reads (17%) | catalogued as rs544491266, COSV57930710; called by muse, mutect2, varscan2
- SRRM3 | c.504C>T p.P168= | Silent (SNP) | VAF 27/182 reads (15%) | called by muse, varscan2
- TMC6 | c.1830G>A p.S610= | Silent (SNP) | VAF 56/202 reads (28%) | catalogued as rs761394043, COSV59808747; called by muse, mutect2, varscan2
- TNFRSF10C | c.90G>A p.R30= | Silent (SNP) | VAF 15/224 reads (7%) | called by muse, mutect2
- TRIO | c.4669C>T p.L1557= | Silent (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2, varscan2
- TYK2 | c.3174C>T p.R1058= | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- ZNF878 | c.1353T>C p.Y451= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as rs543750800; called by muse, mutect2, varscan2
- ABI3BP | c.1576+6291T>A | Intron (SNP) | VAF 34/208 reads (16%) | called by muse, mutect2, varscan2
- C3 | c.4173-42C>A | Intron (SNP) | VAF 29/243 reads (12%) | called by muse, mutect2, varscan2
- CAMKK2 | c.-270G>C | 5'UTR (SNP) | VAF 30/129 reads (23%) | catalogued as rs753934305, COSV61214822; called by muse, mutect2
- DGLUCY | c.1702-3950T>C | Intron (SNP) | VAF 20/92 reads (22%) | called by muse, varscan2
- DPF1 | c.676+248C>T | Intron (SNP) | VAF 50/192 reads (26%) | catalogued as COSV62793007; called by muse, mutect2, varscan2
- FOXP2 | c.*3293A>G | 3'UTR (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- KANK2 | c.1249+113G>A | Intron (SNP) | VAF 10/65 reads (15%) | catalogued as rs766404783, COSV62007341; called by muse, varscan2
- MIA3 | c.3478-1031G>A | Intron (SNP) | VAF 93/207 reads (45%) | catalogued as rs753502540; called by muse, mutect2, varscan2
- MST1L | n.807C>T | RNA (SNP) | VAF 34/174 reads (20%) | catalogued as rs760349909; called by mutect2, varscan2
- NIBAN3 | c.1844-1459C>T | Intron (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- RESP18 | c.233-25G>A | Intron (SNP) | VAF 31/142 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.10360+5130G>T | Intron (SNP) | VAF 67/175 reads (38%) | catalogued as COSV59911256; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23291G>A | Intron (SNP) | VAF 316/763 reads (41%) | catalogued as rs745945267, COSV59384944; called by muse, mutect2, varscan2
